Somatic mutation profile of tumor specimen TCGA-KL-8331-01A (aliquot TCGA-KL-8331-01A-11D-2310-10) from TCGA case TCGA-KL-8331, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 48.5 years (17,710 days).
Specimen TCGA-KL-8331-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cefddc41-ee86-4424-ad09-ad5a3b25cef5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8331-11A (Solid Tissue Normal), aliquot TCGA-KL-8331-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b36d5e8b-1fd5-499f-bd91-6fb47b9c8779

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 15, Silent 10, Splice Region 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN1A | c.136dup p.R46Pfs*2 | Frame Shift Ins (INS) | VAF 17/28 reads (61%) | catalogued as COSV55188784, COSV55189373; called by mutect2, pindel, varscan2
- CPNE7 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV52016707; called by muse, varscan2
- FGG | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271631, COSV60194575; called by muse, mutect2, varscan2
- LRRC38 | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as COSV101065672; called by muse, mutect2, varscan2
- MARCHF5 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1052564009; called by muse, mutect2, varscan2
- PON3 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs772355424; called by muse, mutect2, varscan2
- SCN2A | c.3259G>A p.V1087M | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.025); catalogued as rs765278777, COSV99331813; ClinVar: uncertain significance; called by muse, mutect2
- TMC1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.885); catalogued as rs753977925, COSV52787145; called by muse, mutect2, varscan2
- TNXB | c.4078C>T p.R1360C (on ENST00000647633; = p.R1113C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs367775946; called by muse, mutect2, varscan2
- ZNF185 | c.827+1G>T p.X276_splice | Splice Site (SNP) | VAF 39/97 reads (40%) | catalogued as COSV100248211; called by muse, mutect2, varscan2
- ZNF831 | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs1014228194, COSV64043981; called by muse, mutect2, varscan2
- ABCF2 | c.465C>A p.D155E | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AICDA | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- DHX16 | c.2499G>A p.K833= | Splice Region (SNP) | VAF 35/37 reads (95%) | called by muse, mutect2, varscan2
- GRM3 | c.2496G>T p.K832N | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HS6ST2 | c.441G>T p.M147I | Missense Mutation (SNP) | VAF 100/224 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- NOB1 | c.327G>A p.K109= | Splice Region (SNP) | VAF 63/144 reads (44%) | called by muse, mutect2, varscan2
- PSMC6 | c.181C>G p.L61V (on ENST00000612399; = p.L47V on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRZ1 | c.6802G>T p.D2268Y | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKAP10 | c.1797A>G p.R599= | Silent (SNP) | VAF 49/55 reads (89%) | catalogued as rs1049591; called by muse, mutect2, varscan2
- DMBT1 | c.7122C>T p.V2374= (on ENST00000338354 / NM_001377530.1; = p.V1617= on NM_004406.3) | Silent (SNP) | VAF 134/229 reads (59%) | catalogued as rs758484778, COSV57549968; called by muse, mutect2, varscan2
- IGLON5 | c.420G>A p.S140= | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as rs763452023; called by muse, mutect2, varscan2
- MAGEA10 | c.282C>T p.P94= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as rs750288203; called by muse, mutect2, varscan2
- PAN3 | c.1551A>G p.P517= | Silent (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- PCDH19 | c.1671C>T p.N557= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as rs267606933, CM081730, COSV55269259; called by muse, mutect2, varscan2
- POTEF | c.2448C>T p.R816= | Silent (SNP) | VAF 22/163 reads (13%) | catalogued as rs562326654, COSV100665255, COSV62545450; called by muse, mutect2, varscan2
- RP1L1 | c.4371C>A p.L1457= | Silent (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- SLC29A4 | c.1533C>T p.D511= | Silent (SNP) | VAF 54/111 reads (49%) | catalogued as rs1380806871; called by muse, mutect2, varscan2
- SOAT2 | c.1506C>T p.C502= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs1174487484; called by muse, mutect2, varscan2
